Somatic mutation profile of tumor specimen TCGA-MM-A564-01A (aliquot TCGA-MM-A564-01A-11D-A25V-10) from TCGA case TCGA-MM-A564, project TCGA-KIRC (Kidney Renal Clear Cell Carcinoma). Sex at birth: male; Vital status: Alive; Primary diagnosis: Clear cell adenocarcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage II; Tumor grade: G2; Age at diagnosis: 68.2 years (24,916 days).
Specimen TCGA-MM-A564-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) fb8a2014-a00c-435a-9753-c7752e8a23ee.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-MM-A564-10A (Blood Derived Normal), aliquot TCGA-MM-A564-10A-01D-A25V-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/b7ff00d7-1408-479a-8180-828b19f4e1fa

The open-access MAF lists 89 somatic variants for this specimen: 72 protein-altering or splice-affecting, 16 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 49, Silent 16, Frame Shift Del 12, Nonsense Mutation 4, Splice Region 3, Splice Site 2, 3'UTR 1, In Frame Del 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GPRIN2 | c.298A>C p.T100P | Missense Mutation (SNP) | VAF 11/28 reads (39%) | hotspot (GDC flag); SIFT deleterious (0.01); PolyPhen benign (0.003); catalogued as rs7090312; called by muse, varscan2
- VHL | c.490C>T p.Q164* | Nonsense Mutation (SNP) | VAF 27/66 reads (41%) | catalogued as rs5030819, CM961433, COSV56547270; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ABCC6 | c.4029C>A p.S1343R | Missense Mutation (SNP) | VAF 17/83 reads (20%) | SIFT deleterious (0); PolyPhen benign (0.152); catalogued as COSV99228463; called by muse, mutect2, varscan2
- ACOT8 | c.494C>G p.P165R | Missense Mutation (SNP) | VAF 34/93 reads (37%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.955); catalogued as COSV99467451; called by muse, mutect2, varscan2
- ADAM30 | c.2207A>T p.K736I | Missense Mutation (SNP) | VAF 38/156 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.003); catalogued as COSV101023805; called by muse, mutect2, varscan2
- ARMC9 | c.517C>G p.P173A | Missense Mutation (SNP) | VAF 18/78 reads (23%) | SIFT tolerated (0.29); PolyPhen benign (0.007); catalogued as COSV63023476; called by muse, mutect2, varscan2
- ARSF | c.1456T>A p.Y486N | Missense Mutation (SNP) | VAF 48/86 reads (56%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); catalogued as COSV100839465; called by muse, varscan2
- BBS9 | c.1448G>A p.R483K | Missense Mutation (SNP) | VAF 47/104 reads (45%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99627236; called by muse, mutect2, varscan2
- BRINP3 | c.2068C>T p.P690S | Missense Mutation (SNP) | VAF 136/299 reads (45%) | SIFT tolerated (0.29); PolyPhen possibly damaging (0.878); catalogued as COSV66545169; called by muse, mutect2, varscan2
- CACNA1A | c.1530C>G p.N510K | Missense Mutation (SNP) | VAF 24/102 reads (24%) | SIFT tolerated (0.06); PolyPhen benign (0.154); catalogued as COSV100801838, COSV64194992; called by muse, mutect2, varscan2
- CASTOR1 | c.734C>A p.T245K | Missense Mutation (SNP) | VAF 21/61 reads (34%) | SIFT deleterious (0.02); PolyPhen benign (0.019); catalogued as COSV100355653; called by muse, mutect2, varscan2
- CCT8 | c.8T>C p.L3P | Missense Mutation (SNP) | VAF 31/102 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.694); catalogued as COSV54504867, COSV99725912; called by muse, mutect2, varscan2
- CEP192 | c.4784T>C p.V1595A | Missense Mutation (SNP) | VAF 15/60 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100380949; called by muse, mutect2, varscan2
- CFAP52 | c.407G>C p.S136T | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT tolerated (0.1); PolyPhen benign (0.351); catalogued as COSV100234654, COSV100234984; called by muse, mutect2, varscan2
- CHD5 | c.918C>G p.I306M | Missense Mutation (SNP) | VAF 70/233 reads (30%) | SIFT tolerated (0.13); PolyPhen benign (0.295); catalogued as COSV99313128; called by muse, mutect2, varscan2
- CHGB | c.1066G>T p.D356Y | Missense Mutation (SNP) | VAF 6/40 reads (15%) | SIFT deleterious (0); PolyPhen possibly damaging (0.773); catalogued as COSV100972940, COSV66759920; called by muse, mutect2
- CHIT1 | c.460C>G p.R154G | Missense Mutation (SNP) | VAF 49/202 reads (24%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.6); catalogued as COSV55148192, COSV99705154; called by muse, mutect2, varscan2
- COASY | c.224C>T p.A75V | Missense Mutation (SNP) | VAF 19/84 reads (23%) | SIFT deleterious (0); PolyPhen benign (0.387); catalogued as COSV99888311; called by muse, mutect2, varscan2
- COL27A1 | c.4597G>A p.E1533K | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.604); catalogued as rs753059506, COSV61925497; called by muse, mutect2, varscan2
- COL6A3 | c.7620del p.L2541Cfs*84 | Frame Shift Del (DEL) | VAF 56/256 reads (22%) | catalogued as rs779337122; called by mutect2, pindel, varscan2
- DCLRE1A | c.1837G>T p.D613Y | Missense Mutation (SNP) | VAF 22/80 reads (28%) | SIFT deleterious (0); PolyPhen possibly damaging (0.87); catalogued as rs1564844941, COSV100800294; called by muse, mutect2, varscan2
- DIRAS3 | c.121G>A p.V41M | Missense Mutation (SNP) | VAF 49/188 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63970895; called by muse, mutect2, varscan2
- DST | c.11350G>A p.D3784N (on ENST00000361203 / NM_001374722.1; = p.D1372N on NM_015548.5) | Missense Mutation (SNP) | VAF 43/129 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.155); catalogued as COSV99753745; called by muse, mutect2, varscan2
- DZANK1 | c.92T>C p.L31P | Missense Mutation (SNP) | VAF 15/74 reads (20%) | SIFT tolerated (0.2); PolyPhen benign (0.025); catalogued as COSV99362142; called by muse, mutect2, varscan2
- E2F8 | c.143C>G p.P48R | Missense Mutation (SNP) | VAF 66/167 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV100001416; called by muse, mutect2, varscan2
- EEA1 | c.1592T>A p.L531* | Nonsense Mutation (SNP) | VAF 10/33 reads (30%) | catalogued as COSV100467395; called by mutect2, varscan2
- ETNK1 | c.741C>A p.N247K | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.964); catalogued as COSV99860615; called by muse, mutect2, varscan2
- FAAP100 | c.821T>A p.I274N | Missense Mutation (SNP) | VAF 41/125 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100585296; called by muse, mutect2, varscan2
- FAM90A1 | c.1082G>A p.R361Q | Missense Mutation (SNP) | VAF 13/51 reads (25%) | SIFT tolerated (0.16); PolyPhen benign (0.091); catalogued as rs757101298, COSV100274261, COSV56709974; called by muse, mutect2, varscan2
- FBN1 | c.7744C>G p.Q2582E | Missense Mutation (SNP) | VAF 24/88 reads (27%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.926); catalogued as COSV100354424; called by muse, mutect2, varscan2
- ISOC2 | c.458A>G p.Q153R (on ENST00000425675 / NM_001136201.2; = p.Q169R on NM_024710.3) | Missense Mutation (SNP) | VAF 67/209 reads (32%) | SIFT tolerated (0.4); PolyPhen possibly damaging (0.599); catalogued as COSV99321144; called by muse, mutect2, varscan2
- KCNH5 | c.766G>A p.V256I | Missense Mutation (SNP) | VAF 31/66 reads (47%) | SIFT tolerated (0.38); PolyPhen benign (0.264); catalogued as rs756506083, COSV100525977; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- LRP1B | c.10413C>T p.C3471= | Splice Region (SNP) | VAF 34/141 reads (24%) | catalogued as rs754848419, COSV101254856; called by muse, mutect2, varscan2
- MAF | c.883A>C p.T295P | Missense Mutation (SNP) | VAF 29/97 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100391757; called by muse, mutect2, varscan2
- MTOR | c.1100A>T p.E367V | Missense Mutation (SNP) | VAF 11/34 reads (32%) | SIFT tolerated (0.18); PolyPhen benign (0.045); catalogued as COSV100815895; called by muse, mutect2, varscan2
- NPAS2 | c.273+1G>T p.X91_splice | Splice Site (SNP) | VAF 35/138 reads (25%) | catalogued as COSV100176004; called by muse, mutect2, varscan2
- NPHP3 | c.2251G>T p.V751F | Missense Mutation (SNP) | VAF 17/45 reads (38%) | SIFT deleterious (0.02); PolyPhen benign (0.36); catalogued as COSV100446730; called by muse, mutect2, varscan2
- OR14I1 | c.807T>A p.D269E | Missense Mutation (SNP) | VAF 13/106 reads (12%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.602); catalogued as COSV100700459; called by muse, mutect2, varscan2
- OR14K1 | c.348G>C p.M116I | Missense Mutation (SNP) | VAF 65/332 reads (20%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV99315062; called by muse, mutect2, varscan2
- OR2AG1 | c.26G>A p.G9E | Missense Mutation (SNP) | VAF 37/132 reads (28%) | SIFT tolerated (0.28); PolyPhen benign (0.021); catalogued as rs769650138, COSV56627923; called by muse, mutect2, varscan2
- OR2T35 | c.836C>T p.T279I | Missense Mutation (SNP) | VAF 78/277 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.951); catalogued as rs1300873500; called by muse, mutect2, varscan2
- OR4N5 | c.364C>A p.R122S | Missense Mutation (SNP) | VAF 58/199 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.245); catalogued as rs202234247, COSV61320453; called by muse, mutect2, varscan2
- OR5L1 | c.434C>A p.A145D | Missense Mutation (SNP) | VAF 115/471 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.127); catalogued as rs1243795622, COSV100449993, COSV61734689; called by muse, varscan2
- PDE1B | c.617G>A p.S206N | Missense Mutation (SNP) | VAF 73/275 reads (27%) | SIFT tolerated (0.36); PolyPhen benign (0.13); catalogued as rs774744581, COSV99672364; called by muse, mutect2, varscan2
- PLEKHH1 | c.1628T>C p.I543T | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV61281017; called by muse, mutect2, varscan2
- RAPGEF3 | c.1211T>G p.M404R (on ENST00000389212; = p.M362R on NM_006105.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 56/190 reads (29%) | SIFT tolerated (0.42); PolyPhen benign (0.013); catalogued as COSV99406078; called by muse, mutect2, varscan2
- RYK | c.1786G>A p.V596I (on ENST00000620660 / NM_001005861.2; = p.V593I on NM_002958.4) | Missense Mutation (SNP) | VAF 16/44 reads (36%) | SIFT tolerated (0.42); PolyPhen benign (0.113); catalogued as COSV99938351; called by muse, mutect2, varscan2
- SCG2 | c.22T>C p.W8R | Missense Mutation (SNP) | VAF 22/98 reads (22%) | SIFT tolerated (0.84); PolyPhen benign (0); catalogued as COSV100544663; called by muse, mutect2, varscan2
- SLC18A1 | c.1159C>A p.H387N | Missense Mutation (SNP) | VAF 55/165 reads (33%) | SIFT tolerated (0.19); PolyPhen benign (0.079); catalogued as COSV99368435; called by muse, mutect2, varscan2
- SNAPC3 | c.842A>G p.H281R | Missense Mutation (SNP) | VAF 48/165 reads (29%) | SIFT tolerated (0.27); PolyPhen benign (0.001); catalogued as COSV101070261; called by muse, mutect2, varscan2
- STAG2 | c.1638+1del | Frame Shift Del (DEL) | VAF 54/101 reads (53%) | catalogued as COSV99494477, COSV99495913; called by mutect2, varscan2
- TNNI3K | c.2432-1G>C p.X811_splice | Splice Site (SNP) | VAF 12/204 reads (6%) | catalogued as COSV100436193, COSV58557360; called by muse, mutect2
- TRPM3 | c.1780C>T p.R594W (on ENST00000357533 / NM_001366142.2; = p.R427W on NM_020952.6) | Missense Mutation (SNP) | VAF 25/93 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs1405797336, COSV62582541; called by muse, mutect2, varscan2
- TSPAN32 | c.410G>C p.G137A | Missense Mutation (SNP) | VAF 9/38 reads (24%) | SIFT tolerated (0.12); PolyPhen benign (0.157); catalogued as COSV99478095; called by muse, mutect2, varscan2
- TYMP | c.130C>T p.R44* | Nonsense Mutation (SNP) | VAF 33/107 reads (31%) | catalogued as COSV52689221; called by muse, mutect2, varscan2
- UMODL1 | c.1899+8G>A | Splice Region (SNP) | VAF 40/119 reads (34%) | catalogued as COSV100210650; called by muse, mutect2, varscan2
- USP42 | c.1285G>A p.G429S | Missense Mutation (SNP) | VAF 23/115 reads (20%) | SIFT deleterious (0.04); PolyPhen benign (0.362); catalogued as rs370177935; called by muse, mutect2, varscan2
- ZNF564 | c.232G>T p.D78Y | Missense Mutation (SNP) | VAF 40/141 reads (28%) | SIFT deleterious (0); PolyPhen benign (0); catalogued as COSV100213067; called by muse, mutect2, varscan2
- ZNF831 | c.3874A>C p.R1292= | Splice Region (SNP) | VAF 21/47 reads (45%) | catalogued as COSV100925936; called by muse, mutect2, varscan2
- ANKLE2 | c.437del p.T146Mfs*18 | Frame Shift Del (DEL) | VAF 16/78 reads (21%) | called by mutect2, pindel, varscan2
- AP1G2 | c.1990_1991del p.P664Sfs*10 | Frame Shift Del (DEL) | VAF 15/43 reads (35%) | called by mutect2, pindel, varscan2
- CACNA1H | c.3264del p.K1089Rfs*255 | Frame Shift Del (DEL) | VAF 32/133 reads (24%) | called by mutect2, pindel, varscan2
- DBN1 | c.544del p.E182Sfs*61 | Frame Shift Del (DEL) | VAF 103/273 reads (38%) | called by mutect2, pindel, varscan2
- GSDMB | c.256del p.I86Ffs*5 | Frame Shift Del (DEL) | VAF 24/102 reads (24%) | called by mutect2, pindel, varscan2
- IGSF3 | c.300del p.N101Tfs*37 | Frame Shift Del (DEL) | VAF 68/270 reads (25%) | called by mutect2, pindel, varscan2
- KDM5C | c.2656del p.E886Rfs*49 | Frame Shift Del (DEL) | VAF 16/36 reads (44%) | called by mutect2, pindel, varscan2
- NINL | c.3293del p.N1098Tfs*27 | Frame Shift Del (DEL) | VAF 31/135 reads (23%) | called by mutect2, pindel, varscan2
- PCNT | c.9529_9530del p.L3177Gfs*37 | Frame Shift Del (DEL) | VAF 24/107 reads (22%) | called by mutect2, pindel, varscan2
- PPIL6 | c.383_391del p.T128_F131delinsI | In Frame Del (DEL) | VAF 20/60 reads (33%) | called by mutect2, pindel, varscan2
- SYNE2 | c.5970del p.F1990Lfs*7 | Frame Shift Del (DEL) | VAF 16/88 reads (18%) | called by mutect2, pindel, varscan2
- TBCCD1 | c.225C>A p.Y75* | Nonsense Mutation (SNP) | VAF 3/48 reads (6%) | called by muse, mutect2
- VLDLR | c.913dup p.D305Gfs*5 | Frame Shift Ins (INS) | VAF 71/264 reads (27%) | called by mutect2, pindel, varscan2
- ABCA3 | c.558G>A p.P186= | Silent (SNP) | VAF 19/130 reads (15%) | catalogued as rs747303018, COSV100068249; called by muse, mutect2, varscan2
- ADGRV1 | c.17397G>A p.E5799= | Silent (SNP) | VAF 57/129 reads (44%) | catalogued as rs1201972074, COSV101315698; called by muse, mutect2, varscan2
- CCDC137 | c.606C>T p.V202= | Silent (SNP) | VAF 46/201 reads (23%) | catalogued as COSV100235646; called by muse, mutect2
- HTR4 | c.402C>A p.T134= | Silent (SNP) | VAF 122/220 reads (55%) | catalogued as COSV100087597; called by muse, mutect2, varscan2
- IGDCC3 | c.285C>G p.S95= | Silent (SNP) | VAF 54/175 reads (31%) | catalogued as COSV100030961; called by muse, mutect2, varscan2
- LRP2 | c.408A>T p.G136= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as COSV99787449; called by muse, mutect2, varscan2
- LSR | c.681G>A p.Q227= | Silent (SNP) | VAF 29/128 reads (23%) | catalogued as COSV100670429; called by muse, mutect2, varscan2
- MMRN2 | c.840C>G p.A280= | Silent (SNP) | VAF 32/113 reads (28%) | catalogued as COSV100922723, COSV64400472; called by muse, mutect2, varscan2
- NCLN | c.1668G>A p.L556= | Silent (SNP) | VAF 41/167 reads (25%) | catalogued as COSV99859819; called by muse, mutect2, varscan2
- OR2AG1 | c.27A>G p.G9= | Silent (SNP) | VAF 37/135 reads (27%) | catalogued as COSV100264837; called by muse, mutect2, varscan2
- RUSC2 | c.4473C>A p.P1491= | Silent (SNP) | VAF 36/106 reads (34%) | catalogued as COSV100770661; called by muse, mutect2, varscan2
- SOX5 | c.600G>A p.R200= | Silent (SNP) | VAF 13/85 reads (15%) | catalogued as COSV58622740; called by muse, mutect2, varscan2
- TENM4 | c.6231C>T p.V2077= | Silent (SNP) | VAF 14/420 reads (3%) | catalogued as COSV99572878; called by muse, mutect2
- TLE3 | c.1779C>A p.S593= | Silent (SNP) | VAF 51/165 reads (31%) | catalogued as COSV100450231; called by muse, mutect2, varscan2
- TRIM10 | c.1242T>C p.A414= | Silent (SNP) | VAF 24/79 reads (30%) | catalogued as COSV100939667; called by muse, mutect2, varscan2
- ZNF835 | c.807G>A p.Q269= | Silent (SNP) | VAF 34/73 reads (47%) | catalogued as COSV101606306; called by muse, mutect2, varscan2
- LORICRIN | c.*7del | 3'UTR (DEL) | VAF 27/246 reads (11%) | called by mutect2, pindel, varscan2
